Surgical pathology report (de-identified scan), TCGA case TCGA-2F-A9KT, project TCGA-BLCA (Bladder Urothelial Carcinoma), tissue source site Erasmus MC, specimen TCGA-2F-A9KT-01A (Primary Tumor).

Pathology report

Date of tumor procurement

Date of report

Histologic diagnosis

High grade muscle invasive urothelial cell carcinoma. pT2bG3 N0

Anatomic site and laterality

Posterior bladder wall, right side

Tumor size

7x6x2,5cm

Lymph node status

In total 20 lymph nodes all without tumor localization

Descriptions

ICD-O-3
Carcinoma, urothelial NOS
8120/3
Site Bladder, posterior
wall C67.4
JW 11/29/14

Source: NCI Genomic Data Commons file 83a34034-21d6-4968-a5e6-d9229a4c104f (TCGA-2F-A9KT.EC566A42-E711-458F-8082-1C113AECDF60.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).